Somatic mutation profile of tumor specimen 0DVZ17 from CCDI case PBCNFR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.8 years (5,398 days).
Specimen 0DVZ17: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff2f7379-3ee9-4642-b1c3-bf4fadc82205.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVZ0N (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d19e40c9-b0f4-400b-ab1c-6eea545481b6

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DISP2 | c.3297T>A p.S1099R | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); called by muse, mutect2
- EEF1A2 | c.157T>G p.S53A | Missense Mutation (SNP) | VAF 13/328 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.655); called by muse, mutect2
- HPF1 | c.628A>G p.M210V | Missense Mutation (SNP) | VAF 60/810 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.068); called by muse, mutect2
- SYNM | c.4512C>A p.S1504R (on ENST00000336292 / NM_145728.3; = p.S1192R on NM_015286.6) | Missense Mutation (SNP) | VAF 82/1113 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.249); called by muse, mutect2
- GTSF1L | c.273C>A p.T91= | Silent (SNP) | VAF 27/842 reads (3%) | catalogued as rs1293524827; called by muse, mutect2
